Somatic mutation profile of tumor specimen TCGA-AF-3913-01A (aliquot TCGA-AF-3913-01A-02W-1073-09) from TCGA case TCGA-AF-3913, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.2 years (21,970 days).
Specimen TCGA-AF-3913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccf2509e-b3c3-4436-8cc7-a7a81f74c5b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-3913-11A (Solid Tissue Normal), aliquot TCGA-AF-3913-11A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/323b03f9-8801-4780-966f-3fa41decfb33

The open-access MAF lists 123 somatic variants for this specimen: 85 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 34, Nonsense Mutation 7, Splice Site 3, RNA 2, Frame Shift Del 2, Intron 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3956del p.P1319Lfs*2 | Frame Shift Del (DEL) | VAF 118/193 reads (61%) | catalogued as rs1057517558, COSV57356047, COSV57400437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 44/72 reads (61%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 66/171 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 72/102 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.4672G>T p.V1558L | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT tolerated (0.98); PolyPhen benign (0.009); catalogued as COSV70042286; called by muse, mutect2, varscan2
- ABCA8 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 159/223 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs755088665, COSV52210429, COSV52211116; called by muse, mutect2, varscan2
- ABCB5 | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.113); catalogued as COSV99327008; called by muse, mutect2
- ADAMTSL3 | c.1109G>C p.R370P | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54452219, COSV54466486; called by muse, mutect2, varscan2
- ADNP | c.3266A>G p.H1089R | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV62426691; called by muse, mutect2, varscan2
- ADPRM | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 84/111 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65755252; called by muse, mutect2, varscan2
- AHNAK2 | c.2306C>A p.P769H | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60928523; called by muse, mutect2, varscan2
- ANKS6 | c.2362G>C p.E788Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62051906; called by muse, mutect2, varscan2
- ANO4 | c.765C>A p.F255L (on ENST00000392977 / NM_001286615.2; = p.F220L on NM_178826.4) | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54610971; called by muse, mutect2, varscan2
- ATF4 | c.731G>T p.R244M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.145); catalogued as COSV57480537; called by muse, mutect2, varscan2
- ATF6B | c.633G>A p.W211* | Nonsense Mutation (SNP) | VAF 47/99 reads (47%) | catalogued as COSV64352578; called by muse, mutect2, varscan2
- ATP13A2 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs56170027, COSV100453795; called by muse, mutect2, varscan2
- BTAF1 | c.4898C>A p.T1633N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV56438757; called by muse, mutect2, varscan2
- CACNA1E | c.6175C>T p.R2059W (on ENST00000367573 / NM_001205293.3; = p.R2016W on NM_000721.4) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs750165512, COSV62387407; called by muse, mutect2, varscan2
- CDH9 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV50412963; called by muse, mutect2, varscan2
- CEP44 | c.414T>A p.S138R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.238); catalogued as COSV56660620; called by muse, mutect2, varscan2
- CKMT1A | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV101376806; called by muse, mutect2, varscan2
- COL6A6 | c.3718G>C p.A1240P | Missense Mutation (SNP) | VAF 140/307 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62035636; called by muse, mutect2, varscan2
- CPLANE1 | c.8930C>T p.S2977L | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV57072198; called by muse, mutect2, varscan2
- CTRC | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs367979183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYB5R1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768353653, COSV65917248; called by muse, mutect2, varscan2
- DNAH11 | c.4126G>T p.V1376F | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs531283952, COSV60938522, COSV60977719; called by muse, mutect2, varscan2
- DOCK11 | c.220-1G>C p.X74_splice | Splice Site (SNP) | VAF 183/215 reads (85%) | catalogued as rs1379641028, COSV99352515; called by muse, mutect2, varscan2
- DSPP | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as COSV56809944, COSV56814934; called by muse, mutect2, varscan2
- ECPAS | c.2847C>G p.N949K | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV52206087; called by muse, mutect2, varscan2
- EGLN1 | c.605_615del p.M202Rfs*41 | Frame Shift Del (DEL) | VAF 7/12 reads (58%) | catalogued as COSV64150420; called by mutect2, varscan2
- EXTL2 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64473536; called by muse, mutect2
- FAM90A1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs759052041, COSV56710439; called by muse, mutect2, varscan2
- FIGN | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.212); catalogued as COSV60771259; called by muse, mutect2
- FOXG1 | c.1002C>A p.Y334* | Nonsense Mutation (SNP) | VAF 41/57 reads (72%) | catalogued as COSV57399131; called by muse, mutect2, varscan2
- FOXG1 | c.1003C>G p.P335A | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.428); catalogued as rs531378284, COSV57399147; called by muse, mutect2, varscan2
- FPGT | c.511A>C p.M171L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV63845887; called by muse, mutect2, varscan2
- FRS3 | c.1364A>G p.Y455C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52486315; called by muse, mutect2, varscan2
- GCAT | c.1110C>T p.G370= | Splice Region (SNP) | VAF 22/46 reads (48%) | catalogued as COSV50650096; called by muse, mutect2, varscan2
- GLIS3 | c.331T>A p.S111T | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60934351; called by muse, mutect2, varscan2
- GPAT4 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV67841911; called by muse, mutect2, varscan2
- GTDC1 | c.677G>A p.C226Y | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV54004778; called by muse, mutect2, varscan2
- HIVEP2 | c.5172G>T p.W1724C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50048321; called by muse, mutect2, varscan2
- IDNK | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 149/215 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1475221915, COSV52892480, COSV99461729; called by muse, mutect2, varscan2
- KIRREL2 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV52879710; called by muse, mutect2, varscan2
- LCE3D | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as rs145962377; called by muse, mutect2, varscan2
- LIFR | c.2629G>T p.E877* | Nonsense Mutation (SNP) | VAF 23/176 reads (13%) | catalogued as COSV54688820, COSV54698341; called by muse, mutect2, varscan2
- LONRF3 | c.1859T>A p.F620Y (on ENST00000371628 / NM_001031855.3; = p.F579Y on NM_024778.5) | Missense Mutation (SNP) | VAF 165/182 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59156178; called by muse, mutect2, varscan2
- MATN4 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | PolyPhen probably damaging (0.999); catalogued as COSV59215542; called by muse, mutect2, varscan2
- MYH11 | c.2989C>G p.L997V | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV55567227; called by muse, mutect2
- NAB2 | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 76/96 reads (79%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs200872269, COSV55667774; called by muse, mutect2, varscan2
- NEUROD1 | c.794C>G p.T265S | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1029071008, COSV99716723; called by muse, mutect2
- NFATC2 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV65360357; called by muse, mutect2, varscan2
- OSGIN2 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV52411329; called by muse, mutect2, varscan2
- PCDHA12 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV100248744, COSV56475266; called by muse, mutect2, varscan2
- PCK1 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230588518, COSV60130723; called by muse, mutect2, varscan2
- PCLO | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV61661416; called by muse, mutect2, varscan2
- PDE7B | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV57506523; called by muse, mutect2, varscan2
- PDZD8 | c.3406G>C p.D1136H | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV53693252; called by muse, mutect2, varscan2
- PIK3C2A | c.3169G>C p.G1057R | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV56406478; called by muse, mutect2, varscan2
- PIKFYVE | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as rs61752183, COSV52248250; called by muse, mutect2, varscan2
- PPIP5K2 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58609100; called by muse, mutect2, varscan2
- PRSS12 | c.2083T>G p.Y695D | Missense Mutation (SNP) | VAF 115/301 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1283500521, COSV56609726, COSV56611363; called by muse, mutect2, varscan2
- PTPRT | c.2884+1G>T p.X962_splice | Splice Site (SNP) | VAF 60/330 reads (18%) | catalogued as COSV100623909, COSV61965711; called by muse, mutect2, varscan2
- RAB25 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63108748; called by muse, mutect2, varscan2
- RAPGEF6 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs760104633, COSV57239919; called by muse, mutect2, varscan2
- RUFY1 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as rs755947050, COSV60163399; called by muse, mutect2, varscan2
- RYR3 | c.4180G>C p.D1394H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66806281; called by muse, mutect2, varscan2
- SCN8A | c.3758C>A p.A1253D | Missense Mutation (SNP) | VAF 175/227 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61991859; called by muse, mutect2, varscan2
- SF3B2 | c.259-1G>A p.X87_splice | Splice Site (SNP) | VAF 42/75 reads (56%) | catalogued as COSV59430184; called by muse, mutect2, varscan2
- SGCB | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.876); catalogued as COSV67341463; called by muse, mutect2, varscan2
- SLC12A9 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51936612; called by muse, mutect2, varscan2
- SLC6A15 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 110/152 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs376347410; called by muse, mutect2, varscan2
- SLIT1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs373698645; called by muse, mutect2, varscan2
- SMURF1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs938818363, COSV62816706; called by muse, mutect2, varscan2
- SNW1 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 213/309 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55056467; called by muse, mutect2, varscan2
- SORD | c.1049G>T p.C350F | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51044856; called by muse, mutect2, varscan2
- SPAG1 | c.536A>C p.E179A | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV52561401, COSV52562985; called by muse, mutect2, varscan2
- SPAG17 | c.4256C>A p.S1419Y | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as COSV60455922, COSV60467048, COSV60470771; called by muse, mutect2, varscan2
- STAT2 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 88/111 reads (79%) | catalogued as COSV58477130; called by muse, mutect2, varscan2
- SYK | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 110/156 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65329975; called by muse, mutect2, varscan2
- TAS1R2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs1476026047, COSV64743851; called by muse, mutect2, varscan2
- UBAP2L | c.1645C>A p.L549M | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55180218; called by muse, mutect2, varscan2
- WDR5B | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51659535; called by muse, mutect2, varscan2
- PRICKLE3 | c.893dup p.H298Qfs*15 | Frame Shift Ins (INS) | VAF 131/186 reads (70%) | called by mutect2, pindel, varscan2
- ZNF658 | c.1145T>A p.L382H | Missense Mutation (SNP) | VAF 218/499 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ADAMTS15 | c.405C>T p.V135= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100142950; called by muse, mutect2
- ADAMTS20 | c.1098A>G p.K366= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV101238621; called by muse, mutect2
- ADGRF5 | c.720A>G p.S240= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs771877461, COSV51939253; called by muse, mutect2, varscan2
- ALLC | c.390C>T p.D130= | Silent (SNP) | VAF 82/215 reads (38%) | catalogued as rs201690293, COSV52996364; called by muse, mutect2, varscan2
- ANK1 | c.4794C>T p.H1598= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as rs61753678, COSV55871695; called by muse, mutect2, varscan2
- APLNR | c.993C>T p.C331= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs771763352, COSV57241928; called by muse, mutect2, varscan2
- CACNG3 | c.351C>T p.F117= | Silent (SNP) | VAF 45/131 reads (34%) | catalogued as rs774241889, COSV50064207; called by muse, mutect2, varscan2
- COL6A6 | c.4935C>A p.G1645= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs1279353963, COSV62035646; called by muse, mutect2, varscan2
- CPXCR1 | c.81T>C p.C27= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV52164362; called by muse, mutect2, varscan2
- EXT1 | c.777C>T p.L259= | Silent (SNP) | VAF 102/168 reads (61%) | catalogued as COSV65484162; called by muse, mutect2, varscan2
- FABP2 | c.81G>A p.V27= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV56789224; called by muse, mutect2, varscan2
- FAT1 | c.9183G>A p.T3061= | Silent (SNP) | VAF 51/175 reads (29%) | catalogued as rs773577175, COSV71673562; called by muse, mutect2, varscan2
- FLG2 | c.1506C>A p.S502= | Silent (SNP) | VAF 151/430 reads (35%) | catalogued as rs780039098, COSV66172356; called by muse, mutect2, varscan2
- GJA4 | c.663G>A p.L221= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV60725990; called by muse, mutect2, varscan2
- HYDIN | c.7539A>G p.R2513= | Silent (SNP) | VAF 45/77 reads (58%) | catalogued as COSV59268101; called by muse, mutect2, varscan2
- KCNK3 | c.339C>T p.Y113= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV57191921; called by muse, mutect2, varscan2
- KRT85 | c.1239G>A p.K413= | Silent (SNP) | VAF 22/329 reads (7%) | catalogued as COSV57738086; called by muse, mutect2
- MAGEE2 | c.1131C>T p.I377= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV100972961; called by muse, mutect2
- MKLN1 | c.1842A>G p.R614= | Silent (SNP) | VAF 34/191 reads (18%) | catalogued as rs757478449, COSV61762550; called by muse, mutect2, varscan2
- NEK10 | c.2739C>T p.S913= | Silent (SNP) | VAF 60/92 reads (65%) | catalogued as COSV55364175; called by muse, mutect2, varscan2
- NOLC1 | c.9C>T p.D3= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs540452525, COSV53388140; called by muse, mutect2, varscan2
- NUDCD1 | c.828T>G p.P276= | Silent (SNP) | VAF 40/186 reads (22%) | catalogued as COSV53460154; called by muse, mutect2, varscan2
- PCDH15 | c.945G>A p.P315= | Silent (SNP) | VAF 75/169 reads (44%) | catalogued as rs150450873, COSV57382070; called by muse, mutect2, varscan2
- PCDHGA7 | c.360C>T p.D120= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs768704302, COSV53917402; called by muse, mutect2, varscan2
- PHF24 | c.900C>T p.A300= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as rs374791324; called by muse, mutect2, varscan2
- PRKDC | c.894A>G p.L298= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV58045331, COSV58061753; called by muse, mutect2, varscan2
- RASGRF2 | c.2739G>C p.T913= | Silent (SNP) | VAF 99/297 reads (33%) | catalogued as COSV54134665, COSV54138345; called by muse, mutect2, varscan2
- SLC19A3 | c.1297T>C p.L433= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs766083018, COSV51454572; called by muse, mutect2, varscan2
- ST18 | c.2901G>A p.E967= | Silent (SNP) | VAF 49/98 reads (50%) | catalogued as COSV52507166; called by muse, mutect2, varscan2
- TBC1D3B | c.1398G>C p.G466= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1300595344; called by muse, mutect2
- TET1 | c.5574A>T p.T1858= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV65388931; called by muse, mutect2, varscan2
- TLN2 | c.684C>T p.G228= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as rs759817353, COSV60894927; called by muse, mutect2, varscan2
- TTN | c.77616C>T p.G25872= (on ENST00000591111; = p.G18448= on NM_003319.4) | Silent (SNP) | VAF 41/164 reads (25%) | catalogued as rs775673876, COSV60301046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNK3 | c.4269C>T p.S1423= | Silent (SNP) | VAF 98/115 reads (85%) | catalogued as rs781963579, COSV63615670; called by muse, mutect2, varscan2
- AC016747.4 | n.500C>T | RNA (SNP) | VAF 21/50 reads (42%) | catalogued as rs777489264, COSV54378326; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2647C>T | Intron (SNP) | VAF 9/12 reads (75%) | catalogued as rs745793592, COSV56008847; called by muse, mutect2, varscan2
- RIMS2 | c.4064-21165G>A | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99153244; called by muse, mutect2
- TP73-AS1 | n.1392C>G | RNA (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
